Somatic mutation profile of cancer-model specimen HCM-BROD-0926-C16-85N (3D Organoid; aliquot HCM-BROD-0926-C16-85N-01D-A88G-36), derived from the metastatic tumor of HCMI case HCM-BROD-0926-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 30.9 years (11,285 days).
Specimen HCM-BROD-0926-C16-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1bac705-a2cf-4c71-9ef7-5d4d3a08f764.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0926-C16-10A (Blood Derived Normal), aliquot HCM-BROD-0926-C16-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/093f08d6-93ad-4af7-a9ee-cff52f9a9453

The open-access MAF lists 201 somatic variants for this specimen: 146 protein-altering or splice-affecting, 48 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 48, Nonsense Mutation 7, Frame Shift Del 6, Splice Site 3, Intron 3, Frame Shift Ins 2, 5'Flank 1, 3'Flank 1, In Frame Del 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 337/337 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 199/406 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs769866607; called by muse, mutect2, varscan2
- ADGRB3 | c.3274G>A p.A1092T | Missense Mutation (SNP) | VAF 91/300 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.908); catalogued as rs781253779, COSV53253456; called by muse, mutect2, varscan2
- APOB | c.6973del p.I2325Lfs*6 | Frame Shift Del (DEL) | VAF 60/530 reads (11%) | catalogued as COSV51952357; called by pindel, varscan2
- APOB | c.1755G>C p.Q585H | Missense Mutation (SNP) | VAF 104/672 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV51933716; called by muse, mutect2, varscan2
- BCAR3 | c.486+1G>T p.X162_splice | Splice Site (SNP) | VAF 21/302 reads (7%) | catalogued as COSV99550663; called by muse, mutect2
- BOD1L1 | c.3296G>T p.G1099V | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs949087853; called by muse, mutect2
- CLEC16A | c.3067G>A p.G1023S | Missense Mutation (SNP) | VAF 58/1362 reads (4%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs200315863; called by muse, mutect2
- CNTNAP5 | c.463G>T p.V155L | Missense Mutation (SNP) | VAF 364/365 reads (100%) | SIFT tolerated (0.81); PolyPhen benign (0.357); catalogued as rs1389539692; called by muse, mutect2, varscan2
- COL17A1 | c.3605C>T p.S1202L | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.061); catalogued as rs758851971, COSV62225168; called by muse, mutect2, varscan2
- DHX37 | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 238/438 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0.26); catalogued as rs764393311, COSV58137311; called by muse, mutect2, varscan2
- DPY19L4 | c.2056T>A p.F686I | Missense Mutation (SNP) | VAF 57/498 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs776555307; called by muse, mutect2, varscan2
- FAT3 | c.6143A>G p.E2048G | Missense Mutation (SNP) | VAF 260/724 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV99961836; called by muse, mutect2, varscan2
- FILIP1 | c.1154A>C p.K385T | Missense Mutation (SNP) | VAF 79/538 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52729888; called by muse, mutect2, varscan2
- GAD2 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 235/385 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs182756899; called by muse, mutect2, varscan2
- H4C6 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 101/505 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66685668; called by muse, mutect2, varscan2
- HMCN2 | c.13042C>T p.R4348W | Missense Mutation (SNP) | VAF 61/515 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs766771569; called by muse, mutect2, varscan2
- IGLV7-46 | c.227A>C p.H76P | Missense Mutation (SNP) | VAF 23/374 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1364755795; called by muse, mutect2
- KCNU1 | c.1099C>A p.L367M | Missense Mutation (SNP) | VAF 37/417 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV67758142; called by muse, mutect2
- KRTAP4-12 | c.63C>A p.C21* | Nonsense Mutation (SNP) | VAF 44/1219 reads (4%) | catalogued as COSV67457733; called by muse, mutect2
- LCT | c.3320C>T p.T1107M | Missense Mutation (SNP) | VAF 431/431 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs937987859, COSV51551568, COSV51559414; called by muse, mutect2, varscan2
- LRP1B | c.5093T>C p.L1698P | Missense Mutation (SNP) | VAF 74/309 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67189309; called by muse, mutect2, varscan2
- LRP4 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 268/268 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs138301752; called by muse, mutect2, varscan2
- MUC19 | c.20T>A p.L7H | Missense Mutation (SNP) | VAF 214/436 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.046); catalogued as COSV67127071; called by muse, mutect2, varscan2
- NBEAL1 | c.7194G>C p.E2398D | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1479084918; called by muse, mutect2, varscan2
- ORAI1 | c.26del p.P9Rfs*55 | Frame Shift Del (DEL) | VAF 216/455 reads (47%) | catalogued as rs1555322471; called by mutect2, pindel, varscan2
- PCDH17 | c.3078C>A p.S1026R | Missense Mutation (SNP) | VAF 42/621 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs773733650, COSV64974081; called by muse, mutect2
- PEX5 | c.1553G>A p.R518H (on ENST00000420616; = p.R510H on NM_000319.5) | Missense Mutation (SNP) | VAF 132/278 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as rs146183061; called by muse, mutect2, varscan2
- PIP5K1B | c.500del p.L167Cfs*21 | Frame Shift Del (DEL) | VAF 82/208 reads (39%) | catalogued as COSV55247823, COSV55256034; called by mutect2, pindel, varscan2
- PKLR | c.1501C>T p.Q501* | Nonsense Mutation (SNP) | VAF 92/811 reads (11%) | catalogued as CM950961; called by muse, mutect2, varscan2
- PLCXD2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 48/366 reads (13%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.908); catalogued as COSV67342017; called by muse, varscan2
- RGS7BP | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 112/565 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV61834991; called by muse, mutect2, varscan2
- RTN1 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 391/604 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.366); catalogued as rs1196838903, COSV99954549; called by muse, mutect2, varscan2
- SDK1 | c.6270C>G p.S2090R | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV67393466; called by muse, mutect2
- SLC25A46 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 320/714 reads (45%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV63507323; called by muse, mutect2, varscan2
- SYNE1 | c.14327C>A p.T4776N (on ENST00000367255 / NM_182961.4; = p.T4705N on NM_033071.3) | Missense Mutation (SNP) | VAF 58/333 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as rs1234024087; called by muse, mutect2, varscan2
- TMEM150B | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 140/717 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1033483663, COSV58593651; called by muse, mutect2, varscan2
- TMEM272 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 213/458 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs763643952; called by muse, mutect2, varscan2
- TMTC1 | c.896G>A p.S299N (on ENST00000539277 / NM_001193451.2; = p.S191N on NM_175861.3) | Missense Mutation (SNP) | VAF 58/390 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.107); catalogued as rs1018159546; called by muse, varscan2
- TRIM69 | c.1072C>T p.P358S (on ENST00000329464 / NM_182985.5; = p.P199S on NM_080745.5) | Missense Mutation (SNP) | VAF 58/920 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs372919928; called by muse, mutect2
- UBE2O | c.1126G>T p.A376S | Missense Mutation (SNP) | VAF 125/549 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as rs770134258, COSV100084939; called by muse, mutect2, varscan2
- UBE2Q2 | c.194C>G p.S65C | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV51194884; called by muse, mutect2, varscan2
- VDAC3 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 244/453 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs751469875, COSV99195118; called by muse, mutect2, varscan2
- ZDBF2 | c.3285C>A p.D1095E | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs1396153169, COSV100985570; called by muse, mutect2
- ZFHX3 | c.10537_10569del p.S3513_G3523del | In Frame Del (DEL) | VAF 88/408 reads (22%) | catalogued as rs1567506139; called by pindel, varscan2
- ZNF611 | c.1603G>C p.E535Q | Missense Mutation (SNP) | VAF 23/460 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60542505; called by muse, mutect2
- ZNF99 | c.2330G>A p.R777K | Missense Mutation (SNP) | VAF 82/325 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV68055925, COSV68056592; called by muse, mutect2, varscan2
- ABHD16B | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 396/740 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.041); called by muse, varscan2
- ADAM10 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 34/614 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.396); called by muse, mutect2
- ADGRD2 | c.1597C>G p.H533D | Missense Mutation (SNP) | VAF 69/380 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ALG13 | c.2614C>G p.Q872E | Missense Mutation (SNP) | VAF 56/467 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ALK | c.565C>A p.L189M | Missense Mutation (SNP) | VAF 94/568 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ARID5B | c.2794C>A p.Q932K | Missense Mutation (SNP) | VAF 328/329 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- ATF6B | c.107C>A p.S36Y | Missense Mutation (SNP) | VAF 140/481 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ATR | c.2927C>T p.S976F | Missense Mutation (SNP) | VAF 63/1063 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.055); called by muse, mutect2
- C2CD3 | c.2125G>A p.G709S | Missense Mutation (SNP) | VAF 225/477 reads (47%) | SIFT tolerated (0.81); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- C2orf16 | c.4078G>A p.A1360T | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CACNA1F | c.1724A>T p.E575V | Missense Mutation (SNP) | VAF 22/496 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CBLB | c.1612A>T p.R538* | Nonsense Mutation (SNP) | VAF 59/210 reads (28%) | called by muse, mutect2, varscan2
- CCL3 | c.41C>A p.T14N | Missense Mutation (SNP) | VAF 96/713 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- CDH1 | c.1009-1_1009insTTTG p.X337_splice | Splice Site (INS) | VAF 144/332 reads (43%) | called by mutect2, pindel*, varscan2*
- CDH8 | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 313/653 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP54 | c.3467T>A p.L1156H | Missense Mutation (SNP) | VAF 151/591 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- CFAP74 | c.1774C>A p.L592I | Missense Mutation (SNP) | VAF 40/690 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.253); called by muse, mutect2
- CMTM1 | c.197_198dup p.T67* (on ENST00000457188 / NM_181269.3; = p.T184* on NM_052999.4) | Frame Shift Ins (INS) | VAF 156/408 reads (38%) | called by mutect2, pindel, varscan2
- CMYA5 | c.9922G>A p.V3308I | Missense Mutation (SNP) | VAF 91/403 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- CNTN4 | c.2504G>T p.G835V | Missense Mutation (SNP) | VAF 13/209 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- COL24A1 | c.1637C>A p.P546H | Missense Mutation (SNP) | VAF 152/152 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- CPSF6 | c.469A>C p.T157P | Missense Mutation (SNP) | VAF 106/449 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- DCBLD1 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 67/517 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DNAH7 | c.3645A>T p.R1215S | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- DNAH7 | c.3644G>A p.R1215K | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- DOC2B | c.912del p.Y305Tfs*2 | Frame Shift Del (DEL) | VAF 66/561 reads (12%) | called by mutect2, pindel, varscan2
- DPYSL2 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 31/283 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.095); called by muse, mutect2
- DZANK1 | c.378+1G>T p.X126_splice | Splice Site (SNP) | VAF 16/150 reads (11%) | called by muse, mutect2
- EIF1B | c.94C>G p.H32D | Missense Mutation (SNP) | VAF 72/319 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- EPB41L3 | c.2397C>A p.F799L | Missense Mutation (SNP) | VAF 35/269 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM135B | c.4106C>T p.A1369V | Missense Mutation (SNP) | VAF 94/679 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAM135B | c.1614A>C p.R538S | Missense Mutation (SNP) | VAF 51/648 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- FAR1 | c.653A>T p.E218V | Missense Mutation (SNP) | VAF 98/392 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FAT3 | c.5281G>C p.D1761H | Missense Mutation (SNP) | VAF 52/648 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FETUB | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 177/815 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- FGA | c.377C>G p.T126S | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FSCN3 | c.1045A>G p.I349V | Missense Mutation (SNP) | VAF 24/698 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.061); called by muse, mutect2
- GCM2 | c.1015A>G p.K339E | Missense Mutation (SNP) | VAF 119/350 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- GRM7 | c.2721T>A p.Y907* | Nonsense Mutation (SNP) | VAF 22/321 reads (7%) | called by muse, mutect2
- HIVEP2 | c.1832A>G p.H611R | Missense Mutation (SNP) | VAF 22/684 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.188); called by muse, mutect2
- HRG | c.110T>A p.L37Q | Missense Mutation (SNP) | VAF 61/976 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.664); called by muse, mutect2
- HTT | c.1951G>C p.D651H | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- IGSF10 | c.6920A>T p.D2307V | Missense Mutation (SNP) | VAF 38/725 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IKBKB | c.383A>T p.D128V | Missense Mutation (SNP) | VAF 90/476 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INTS7 | c.1127A>G p.E376G | Missense Mutation (SNP) | VAF 61/262 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- KCNH5 | c.845A>C p.K282T | Missense Mutation (SNP) | VAF 56/421 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- KCNQ3 | c.1064T>A p.L355Q | Missense Mutation (SNP) | VAF 56/464 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, varscan2
- KIF4B | c.2545A>G p.R849G | Missense Mutation (SNP) | VAF 78/806 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2
- KIR3DL2 | c.758A>C p.Y253S | Missense Mutation (SNP) | VAF 38/352 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLK9 | c.100C>A p.Q34K | Missense Mutation (SNP) | VAF 96/582 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LMOD2 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 25/450 reads (6%) | called by muse, mutect2
- LONRF3 | c.173A>T p.Q58L | Missense Mutation (SNP) | VAF 20/664 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- MECOM | c.353T>C p.L118S (on ENST00000468789 / NM_001105078.4; = p.L306S on NM_004991.4) | Missense Mutation (SNP) | VAF 403/1014 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- MEIS2 | c.746G>T p.S249I (on ENST00000561208 / NM_170675.5; = p.S236I on NM_002399.3) | Missense Mutation (SNP) | VAF 210/210 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- MMRN1 | c.2789T>C p.M930T | Missense Mutation (SNP) | VAF 135/585 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MTHFS | c.206A>T p.K69M | Missense Mutation (SNP) | VAF 39/340 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- MYO10 | c.5545C>T p.P1849S | Missense Mutation (SNP) | VAF 236/585 reads (40%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- NCAM1 | c.2323G>T p.G775C (on ENST00000316851 / NM_181351.5; = p.G765C on NM_000615.7) | Missense Mutation (SNP) | VAF 16/549 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NID1 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 329/330 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- OR2A7 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 51/390 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- OSTN | c.230A>G p.E77G | Missense Mutation (SNP) | VAF 127/649 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTUD7A | c.2044_2087del p.D682Hfs*188 (on ENST00000307050 / NM_001382637.1; = p.D675Hfs*188 on NM_130901.3) | Frame Shift Del (DEL) | VAF 166/310 reads (54%) | called by mutect2, pindel, varscan2
- PCMTD2 | c.546A>C p.K182N | Missense Mutation (SNP) | VAF 44/605 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.678); called by muse, mutect2
- PDE10A | c.1773G>C p.M591I | Missense Mutation (SNP) | VAF 105/300 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PEX19 | c.50A>T p.E17V | Missense Mutation (SNP) | VAF 54/772 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2
- PGAP1 | c.1524C>G p.N508K | Missense Mutation (SNP) | VAF 75/224 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- PIEZO2 | c.7886A>G p.E2629G | Missense Mutation (SNP) | VAF 68/388 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PIEZO2 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 283/284 reads (100%) | called by muse, mutect2, varscan2
- PITPNM1 | c.3397G>C p.A1133P | Missense Mutation (SNP) | VAF 96/699 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- PKHD1L1 | c.6887del p.P2296Lfs*2 | Frame Shift Del (DEL) | VAF 36/254 reads (14%) | called by mutect2, pindel*, varscan2
- PNPLA2 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 37/297 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- PRKG2 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PURB | c.787A>C p.K263Q | Missense Mutation (SNP) | VAF 16/482 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2
- RFX1 | c.117G>T p.Q39H | Missense Mutation (SNP) | VAF 26/414 reads (6%) | SIFT tolerated, low confidence (0.59); PolyPhen probably damaging (0.979); called by muse, mutect2
- RLF | c.2048A>C p.K683T | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF146 | c.439G>A p.A147T (on ENST00000368314 / NM_001242850.2; = p.A146T on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/384 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- RNF180 | c.190G>C p.V64L | Missense Mutation (SNP) | VAF 184/354 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPGRIP1 | c.334C>A p.R112S | Missense Mutation (SNP) | VAF 66/1130 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2
- SFPQ | c.288G>T p.Q96H | Missense Mutation (SNP) | VAF 240/779 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SLAMF1 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 20/604 reads (3%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.805); called by muse, mutect2
- SLC37A2 | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 40/652 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.084); called by muse, mutect2
- SNX19 | c.2017G>A p.V673I | Missense Mutation (SNP) | VAF 115/468 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SOCS7 | c.584G>A p.S195N | Missense Mutation (SNP) | VAF 153/1144 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.961); called by muse, varscan2
- SPTA1 | c.958G>T p.V320L | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- STX11 | c.482T>A p.I161N | Missense Mutation (SNP) | VAF 92/743 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SUCLG2 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SULF2 | c.642G>T p.R214S | Missense Mutation (SNP) | VAF 20/708 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); called by muse, mutect2
- TAF1 | c.4316A>G p.Y1439C (on ENST00000373790 / NM_138923.4; = p.Y1460C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 243/243 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF1L | c.3173C>T p.S1058F | Missense Mutation (SNP) | VAF 120/653 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- TCF20 | c.2143T>G p.S715A | Missense Mutation (SNP) | VAF 38/779 reads (5%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); called by muse, mutect2
- TERB2 | c.9A>T p.Q3H | Missense Mutation (SNP) | VAF 64/327 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- TGS1 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 51/321 reads (16%) | called by muse, mutect2, varscan2
- TLX3 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 527/1029 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TMEM235 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 103/629 reads (16%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- TRPM4 | c.1586C>T p.P529L | Missense Mutation (SNP) | VAF 124/552 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- VEGFA | c.355G>C p.E119Q (on ENST00000523873 / NM_001171623.1; = p.E299Q on NM_003376.6) | Missense Mutation (SNP) | VAF 150/485 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ZCWPW1 | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 46/501 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- ZNF256 | c.422T>A p.V141D | Missense Mutation (SNP) | VAF 59/566 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ZSWIM5 | c.2672dup p.L891Ffs*28 | Frame Shift Ins (INS) | VAF 41/396 reads (10%) | called by mutect2, pindel, varscan2
- ANAPC1 | c.2556G>A p.L852= | Silent (SNP) | VAF 59/379 reads (16%) | called by muse, mutect2, varscan2
- BCL3 | c.1086C>T p.A362= | Silent (SNP) | VAF 320/470 reads (68%) | called by muse, mutect2, varscan2
- C5 | c.253T>C p.L85= | Silent (SNP) | VAF 33/101 reads (33%) | called by muse, mutect2, varscan2
- C6orf141 | c.447G>T p.R149= | Silent (SNP) | VAF 177/594 reads (30%) | called by muse, mutect2, varscan2
- DCC | c.1752A>G p.K584= | Silent (SNP) | VAF 36/313 reads (12%) | called by muse, mutect2, varscan2
- DENND4A | c.4296G>A p.A1432= | Silent (SNP) | VAF 194/480 reads (40%) | catalogued as rs781718938; called by muse, mutect2, varscan2
- FAM47B | c.1045C>T p.L349= | Silent (SNP) | VAF 262/262 reads (100%) | called by muse, mutect2, varscan2
- FYN | c.762C>T p.T254= | Silent (SNP) | VAF 50/489 reads (10%) | catalogued as rs768403035; called by muse, mutect2, varscan2
- FZD10 | c.864C>T p.I288= | Silent (SNP) | VAF 354/831 reads (43%) | catalogued as COSV57471949; called by muse, mutect2, varscan2
- GIMD1 | c.24C>T p.I8= | Silent (SNP) | VAF 259/491 reads (53%) | catalogued as rs1405176567; called by muse, mutect2, varscan2
- GSC2 | c.6G>A p.A2= | Silent (SNP) | VAF 387/389 reads (99%) | called by muse, mutect2, varscan2
- HRNR | c.6576G>A p.S2192= | Silent (SNP) | VAF 368/2264 reads (16%) | catalogued as rs567290240, COSV64260199, COSV64260339; called by muse, varscan2
- HS3ST4 | c.1272C>T p.V424= | Silent (SNP) | VAF 67/754 reads (9%) | catalogued as COSV58821549; called by muse, mutect2
- HSPG2 | c.7941G>A p.L2647= | Silent (SNP) | VAF 50/464 reads (11%) | called by muse, mutect2, varscan2
- IDUA | c.1287C>T p.G429= | Silent (SNP) | VAF 150/545 reads (28%) | called by muse, mutect2, varscan2
- IGHM | c.1104G>A p.R368= | Silent (SNP) | VAF 66/684 reads (10%) | called by muse, mutect2, varscan2
- KIAA1210 | c.3207T>A p.T1069= | Silent (SNP) | VAF 59/404 reads (15%) | called by muse, mutect2, varscan2
- KIF1A | c.4404G>T p.T1468= (on ENST00000320389 / NM_001379639.1; = p.T1460= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 470/471 reads (100%) | called by muse, mutect2, varscan2
- KLK9 | c.99C>A p.S33= | Silent (SNP) | VAF 96/583 reads (16%) | called by muse, mutect2, varscan2
- LCMT1 | c.636C>G p.L212= | Silent (SNP) | VAF 326/674 reads (48%) | called by muse, mutect2, varscan2
- LRP6 | c.2013G>A p.V671= | Silent (SNP) | VAF 49/303 reads (16%) | called by muse, mutect2, varscan2
- MCHR2 | c.822C>T p.N274= | Silent (SNP) | VAF 147/461 reads (32%) | called by muse, mutect2, varscan2
- NBDY | c.87C>T p.L29= | Silent (SNP) | VAF 24/454 reads (5%) | called by muse, mutect2
- NOP53 | c.1153C>T p.L385= | Silent (SNP) | VAF 216/1098 reads (20%) | called by muse, mutect2
- OSBPL7 | c.873G>A p.L291= | Silent (SNP) | VAF 640/640 reads (100%) | called by muse, mutect2, varscan2
- OSER1 | c.162C>T p.T54= | Silent (SNP) | VAF 22/424 reads (5%) | called by muse, mutect2
- PAIP1 | c.63C>G p.R21= | Silent (SNP) | VAF 117/1095 reads (11%) | called by muse, mutect2, varscan2
- PCDH11X | c.3615C>T p.I1205= | Silent (SNP) | VAF 607/607 reads (100%) | catalogued as rs768994403, COSV53455584, COSV53502052; called by muse, mutect2, varscan2
- PLEKHG6 | c.2145G>A p.E715= | Silent (SNP) | VAF 121/603 reads (20%) | catalogued as rs1044736173; called by muse, mutect2, varscan2
- PPP1R37 | c.1965C>T p.V655= | Silent (SNP) | VAF 40/732 reads (5%) | called by muse, mutect2
- PRKG2 | c.771A>T p.L257= | Silent (SNP) | VAF 24/222 reads (11%) | called by muse, mutect2, varscan2
- PRODH2 | c.543C>T p.L181= (on ENST00000301175; = p.L105= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 72/456 reads (16%) | catalogued as rs780138472; called by muse, mutect2, varscan2
- PRSS54 | c.117C>T p.Y39= | Silent (SNP) | VAF 99/630 reads (16%) | catalogued as rs1414039933, COSV54689347; called by muse, mutect2, varscan2
- SEMA5A | c.822T>A p.A274= | Silent (SNP) | VAF 62/654 reads (9%) | called by muse, mutect2
- SLC41A3 | c.171T>C p.P57= | Silent (SNP) | VAF 63/627 reads (10%) | called by muse, mutect2, varscan2
- SRSF2 | c.477G>A p.S159= | Silent (SNP) | VAF 118/1340 reads (9%) | called by muse, mutect2
- STAP1 | c.516G>A p.L172= | Silent (SNP) | VAF 155/155 reads (100%) | called by muse, mutect2, varscan2
- STX11 | c.483C>A p.I161= | Silent (SNP) | VAF 93/742 reads (13%) | called by muse, mutect2, varscan2
- TCHH | c.3399C>T p.R1133= | Silent (SNP) | VAF 104/782 reads (13%) | called by muse, varscan2
- TFDP1 | c.933G>A p.S311= | Silent (SNP) | VAF 168/772 reads (22%) | catalogued as rs147172256, COSV100945671; called by muse, mutect2, varscan2
- TLX3 | c.276G>T p.A92= | Silent (SNP) | VAF 530/1032 reads (51%) | catalogued as rs1352133888, COSV51540705; called by muse, mutect2, varscan2
- TMCO6 | c.123C>T p.S41= | Silent (SNP) | VAF 66/499 reads (13%) | catalogued as rs1296832760; called by muse, mutect2, varscan2
- UBQLN3 | c.1074T>G p.T358= | Silent (SNP) | VAF 56/368 reads (15%) | catalogued as COSV100293278, COSV61163164; called by muse, mutect2, varscan2
- UNCX | c.921G>A p.A307= | Silent (SNP) | VAF 523/525 reads (100%) | catalogued as rs751232846; called by muse, varscan2
- VIL1 | c.1884T>A p.T628= | Silent (SNP) | VAF 59/526 reads (11%) | called by muse, mutect2, varscan2
- ZBTB45 | c.1449C>G p.P483= | Silent (SNP) | VAF 233/873 reads (27%) | called by muse, mutect2, varscan2
- ZNF430 | c.423A>G p.E141= | Silent (SNP) | VAF 44/253 reads (17%) | catalogued as rs1304959657; called by muse, mutect2, varscan2
- ZNF560 | c.2247C>T p.F749= | Silent (SNP) | VAF 80/379 reads (21%) | catalogued as COSV56869936; called by muse, mutect2, varscan2
- ARHGAP21 | c.4150+750A>C | Intron (SNP) | VAF 35/322 reads (11%) | called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57621690 A>T | 3'Flank (SNP) | VAF 74/404 reads (18%) | catalogued as rs931317892, COSV54089679; called by muse, mutect2
- ARMCX4 | c.1039-2905G>A | Intron (SNP) | VAF 92/287 reads (32%) | catalogued as rs781889713; called by muse, mutect2, varscan2
- KCNQ1 | c.1393+21485T>G | Intron (SNP) | VAF 32/137 reads (23%) | called by muse, mutect2, varscan2
- Y_RNA | chr3:48286251 G>A | 5'Flank (SNP) | VAF 81/388 reads (21%) | called by muse, mutect2
- ZNF81 | c.*683G>A | 3'UTR (SNP) | VAF 207/207 reads (100%) | called by muse, mutect2, varscan2
- ZNF812P | n.663T>G | RNA (SNP) | VAF 30/351 reads (9%) | called by muse, mutect2
